Somatic mutation profile of tumor specimen MP2PRT-PAPDFA-TMP1-A (aliquot MP2PRT-PAPDFA-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PAPDFA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,392 days).
Specimen MP2PRT-PAPDFA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5423e7e9-6ab4-450f-a6d8-500498d4a706.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPDFA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPDFA-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1be35c1d-0168-4bfc-803e-0665c10d0d44

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Nonsense Mutation 1, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK2 | c.10646G>A p.R3549H | Missense Mutation (SNP) | VAF 182/459 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs768351547; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT3 | c.5197C>T p.R1733C | Missense Mutation (SNP) | VAF 86/365 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as rs374615122; called by muse, mutect2, varscan2
- CALHM3 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 319/765 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGHV3-53 | c.349_350insTTCGAGAG | In Frame Ins (INS) | VAF 30/72 reads (42%) | called by pindel, varscan2
- TMEM229A | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 357/895 reads (40%) | called by muse, mutect2, varscan2
- IGFN1 | c.1083C>T p.D361= | Silent (SNP) | VAF 244/674 reads (36%) | catalogued as rs367631324; called by muse, mutect2, varscan2
- SMTN | c.354A>T p.V118= | Silent (SNP) | VAF 42/476 reads (9%) | called by muse, mutect2
- LMO7 | c.322-146C>G | Intron (SNP) | VAF 115/393 reads (29%) | called by muse, mutect2, varscan2
